Gene-level copy-number profile of tumor specimen MP2PRT-PATARG-TMP1-A from MP2PRT case MP2PRT-PATARG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,224 days).
Specimen MP2PRT-PATARG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6dfd8ceb-ac97-4c1e-8dc7-b8624219dc60.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATARG-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/454a762c-35ca-4802-9d45-260827563d08

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 53; copy number 1: 561; copy number 2: 41,704; copy number 3: 80; copy number 4: 4,606; copy number 5: 11,130; copy number 6: 39; copy number 7: 46; copy number 8: 676; copy number 9: 10.

Homozygous deletions (total copy number 0; autosomes only): 53 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,040,224–89,085,787, 4 genes (within-gene range 0–1): IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15.
- chr2:89,234,174–89,254,015, 4 genes (within-gene range 0–1): IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32.
- chr14:22,415,362–22,465,787, 9 genes (within-gene range 0–5): AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ2, TRDJ3, TRDC.
- chr14:105,881,034–106,005,574, 35 genes (within-gene range 0–5): IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3.
- chr15:25,848,747–25,848,825, 1 gene (within-gene range 0–2): MIR4715.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11,901 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–49,246,915, 706 genes, copy number 5 (broad region; genes not listed).
- chr4:51,843,000–190,092,279, 1,850 genes, copy number 5 (broad region; genes not listed).
- chr8:64,091–8,049,267, 174 genes, copy number 5 (broad region; genes not listed).
- chr8:8,086,022–8,116,949, 4 genes, copy number 5: AC105233.2, MIR548I3, RPS3AP31, SNRPCP17.
- chr8:8,228,595–145,066,685, 2,222 genes, copy number 5–9 (within-gene range 3–9) (broad region; genes not listed).
- chr10:87,859,158–88,259,372, 7 genes, copy number 5: KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1.
- chr14:18,623,852–22,334,685, 250 genes, copy number 5–6 (broad region; genes not listed).
- chr14:22,469,041–101,022,132, 1,583 genes, copy number 5 (within-gene range 0–5) (broad region; genes not listed).
- chr14:104,223,584–105,845,678, 69 genes, copy number 5 (within-gene range 0–5) (broad region; genes not listed).
- chr14:106,301,396–106,879,812, 94 genes, copy number 5 (broad region; genes not listed).
- chr17:142,789–39,747,291, 1,478 genes, copy number 5 (broad region; genes not listed).
- chr17:39,980,807–83,240,804, 1,533 genes, copy number 5 (broad region; genes not listed).
- chr18:45,034–80,247,514, 1,199 genes, copy number 5 (broad region; genes not listed).
- chr21:9,369,285–9,914,846, 10 genes, copy number 5: CR381653.2, NCOR1P4, AC124864.1, AC124864.2, U1, LINC01667, AC018692.2, RN7SL52P, SNORA70, AC018692.1.
- chr21:13,038,160–46,691,226, 722 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 49. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
